Somatic mutation profile of tumor specimen TCGA-ZD-A8I3-01A (aliquot TCGA-ZD-A8I3-01A-11D-A417-09) from TCGA case TCGA-ZD-A8I3, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 73.2 years (26,754 days).
Specimen TCGA-ZD-A8I3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da0c9da5-e9f9-451d-92d7-b4e98432a76e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZD-A8I3-10A (Blood Derived Normal), aliquot TCGA-ZD-A8I3-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0d21c1a-de6e-4184-b039-d0f4237102c9

The open-access MAF lists 39 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 4, Frame Shift Del 3, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by mutect2, varscan2
- ABCC1 | c.2296G>A p.V766M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296672475, COSV60679559; called by muse, mutect2, varscan2
- AHNAK | c.9360G>C p.M3120I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99949220; called by muse, mutect2, varscan2
- ARID4B | c.3881T>C p.L1294S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs767716325; called by muse, mutect2, varscan2
- CDH5 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as rs375751151; called by muse, mutect2, varscan2
- CHIA | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58475679; called by muse, mutect2, varscan2
- CRYBG1 | c.4979C>G p.A1660G | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV64811899; called by muse, mutect2, varscan2
- CTNNA2 | c.1942G>T p.D648Y | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV58167191; called by muse, mutect2
- INTS8 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV58252052; called by muse, mutect2
- MOSPD2 | c.1349C>A p.P450Q | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs1261685821, COSV66860775; called by muse, mutect2, varscan2
- PDE4B | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs777331308, COSV58488888; called by muse, mutect2, varscan2
- SAGE1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1556598908; called by muse, mutect2, varscan2
- ZHX3 | c.569T>C p.M190T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs769564525; called by muse, mutect2, varscan2
- ANK2 | c.4426dup p.N1476Kfs*2 | Frame Shift Ins (INS) | VAF 42/130 reads (32%) | called by mutect2, pindel, varscan2
- ARID1A | c.4666_4676del p.G1556Pfs*12 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- ATP2B1 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QTNF9 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- CSMD1 | c.6312C>G p.Y2104* (on ENST00000520002; = p.Y2103* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- DAXX | c.26T>A p.V9E | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GDI1 | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LAMA1 | c.4717G>C p.D1573H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- LRP1 | c.3584A>G p.N1195S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); called by muse, mutect2
- LRP1B | c.1416C>G p.S472R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- NPFFR1 | c.221T>A p.M74K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1 | c.4351C>G p.P1451A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PRICKLE3 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.304); called by muse, mutect2
- RGS20 | c.645T>A p.C215* (on ENST00000297313 / NM_170587.4; = p.C68* on NM_003702.4) | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- SMG8 | c.971A>C p.N324T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPRED1 | c.1069_1078del p.D357Kfs*46 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by pindel, varscan2
- SPRED1 | c.1083A>C p.R361S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.696); called by muse, varscan2
- STOX1 | c.1705_1709del p.P569Cfs*6 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- CDH7 | c.768C>T p.N256= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs763088891; called by muse, mutect2, varscan2
- CDX4 | c.849C>T p.S283= | Silent (SNP) | VAF 24/318 reads (8%) | catalogued as rs889777082, COSV100999140; called by muse, mutect2
- CHD9 | c.1284A>G p.S428= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs778047436; called by muse, varscan2
- FARS2 | c.966C>T p.I322= | Silent (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- PIK3R6 | c.978G>A p.P326= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs765808742, COSV61006109; called by muse, mutect2, varscan2
- SSTR4 | c.732C>T p.R244= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs369953610; called by muse, mutect2, varscan2
- TULP1 | c.264C>T p.Y88= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs1163750703, COSV57692851; called by muse, mutect2, varscan2
- MDM4 | c.412-218G>T | Intron (SNP) | VAF 3/49 reads (6%) | catalogued as COSV65796696; called by muse, mutect2
